CCDI case PBBUCK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c7bd161d-1670-4c95-8ab1-6b34a6ff0cd0

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, benign: ICD-O-3 morphology code: 8000/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.6 years (4,979 days).

Biospecimens (3 samples)
- Sample 0DIOJV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIOK4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIOKC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
